Somatic mutation profile of tumor specimen TCGA-VP-AA1N-01A (aliquot TCGA-VP-AA1N-01A-31D-A41K-08) from TCGA case TCGA-VP-AA1N, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.6 years (25,781 days).
Specimen TCGA-VP-AA1N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b01a990d-28b3-490e-bee5-1174b72e7f24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VP-AA1N-10A (Blood Derived Normal), aliquot TCGA-VP-AA1N-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37007300-476f-4cb4-9d32-e20de077820a

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 22, Silent 7, Frame Shift Del 2, In Frame Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALYREF | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100485804, COSV58668374; called by muse, mutect2, varscan2
- ANKRD30A | c.1902G>C p.E634D (on ENST00000611781; = p.E578D on NM_052997.2) | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.051); catalogued as COSV100653159; called by muse, mutect2
- AVEN | c.386A>G p.N129S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.085); catalogued as rs370441123; called by muse, mutect2, varscan2
- B3GNT7 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs777700169, COSV99805816; called by muse, mutect2, varscan2
- BAHD1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763869841, COSV69084834; called by muse, mutect2, varscan2
- BARD1 | c.1652C>T p.S551L | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs587781707, BM1484556, COSV99638254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C1S | c.1633G>A p.V545I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs782412161, COSV61071351; called by muse, mutect2, varscan2
- CECR2 | c.2953C>A p.P985T (on ENST00000342247 / NM_001290047.2; = p.P801T on NM_001290046.1) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV99377399; called by muse, mutect2
- CSMD3 | c.2453C>A p.S818* (on ENST00000297405 / NM_001363185.1; = p.S714* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as COSV99829197; called by muse, varscan2
- KLHL22 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs1259278556, COSV100185893; called by muse, varscan2
- KMT2C | c.12847A>C p.N4283H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100069343; called by muse, mutect2, varscan2
- LRRC1 | c.137A>G p.N46S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746104594, COSV63824666; called by muse, mutect2, varscan2
- LUZP2 | c.599A>T p.E200V | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV100419391; called by muse, mutect2, varscan2
- MAP11 | c.961G>C p.G321R | Missense Mutation (SNP) | VAF 84/170 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs764234323, COSV100385411; called by muse, mutect2, varscan2
- MUC2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs534651955; called by muse, mutect2
- MYH13 | c.4913G>A p.R1638H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs1567655857, COSV52848279; called by muse, mutect2, varscan2
- OBSCN | c.11722A>C p.T3908P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.891); catalogued as COSV52757705, COSV99475336; called by muse, mutect2, varscan2
- PELO | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99250944; called by muse, mutect2, varscan2
- PROKR2 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99450049; called by muse, mutect2, varscan2
- SDF2L1 | c.486C>G p.F162L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.324); catalogued as COSV50708068, COSV99963619; called by muse, mutect2
- SERPINA1 | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV100872038; called by muse, mutect2
- TTF1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.074); catalogued as COSV100524596; called by muse, mutect2, varscan2
- ZNF641 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99973415; called by muse, mutect2, varscan2
- FOXA1 | c.752_760del p.G251_F254delinsV | In Frame Del (DEL) | VAF 8/21 reads (38%) | called by mutect2, varscan2
- OMD | c.896del p.P299Qfs*14 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- TMEM179B | c.552_554del p.V185del | In Frame Del (DEL) | VAF 64/158 reads (41%) | called by mutect2, pindel, varscan2
- WSCD1 | c.94del p.L32Cfs*61 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- ACHE | c.1257C>T p.P419= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs199872491, COSV53816996; called by muse, mutect2, varscan2
- ADAMTS10 | c.690C>T p.G230= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs1568404910, COSV99546652; called by muse, mutect2, varscan2
- CAVIN1 | c.606G>A p.S202= | Silent (SNP) | VAF 10/143 reads (7%) | catalogued as rs1311933935, COSV100824520; called by muse, mutect2
- HEATR5B | c.3720T>C p.F1240= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99248735; called by muse, mutect2, varscan2
- PAQR4 | c.267C>T p.C89= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99233951; called by muse, mutect2, varscan2
- PRF1 | c.1137G>A p.R379= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV64614878; called by muse, mutect2, varscan2
- TASOR2 | c.150G>T p.P50= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs375654540, COSV100050157; called by muse, mutect2, varscan2
